Somatic mutation profile of tumor specimen TCGA-64-1680-01A (aliquot TCGA-64-1680-01A-02W-0928-08) from TCGA case TCGA-64-1680, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.7 years (23,267 days).
Specimen TCGA-64-1680-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1b055bf-b91a-4aeb-88a8-ef30662b2c22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-64-1680-10A (Blood Derived Normal), aliquot TCGA-64-1680-10A-01D-1040-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ebaff32-1172-4b1b-bb0d-bf0b71b8c5fd

The open-access MAF lists 49 somatic variants for this specimen: 38 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 31, Silent 11, Nonsense Mutation 3, Frame Shift Del 1, In Frame Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM21 | c.562G>C p.E188Q | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50799211; called by muse, mutect2
- ADGRB2 | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.523); catalogued as rs756718959, COSV57075488; called by muse, mutect2, varscan2
- ARHGEF2 | c.923G>T p.G308V (on ENST00000361247 / NM_001162383.2; = p.G280V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV58117789; called by muse, mutect2, varscan2
- ARID2 | c.4688G>C p.S1563T | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57615901; called by muse, mutect2
- ATP2B2 | c.1828C>T p.R610C (on ENST00000352432; = p.R576C on NM_001683.5) | Missense Mutation (SNP) | VAF 79/151 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757018981, COSV100659980, COSV59498430; called by muse, mutect2, varscan2
- BDP1 | c.6201A>C p.R2067S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV62435287; called by muse, mutect2, varscan2
- CCT4 | c.734A>C p.K245T | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV66702193; called by muse, mutect2, varscan2
- CDK12 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.945); catalogued as rs759485356, COSV70999458, COSV71000630; called by mutect2, varscan2
- CNOT2 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 19/348 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV57507495; called by muse, mutect2
- FBXO30 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 81/237 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52792614; called by muse, mutect2, varscan2
- GATA3 | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV60522889; called by muse, mutect2, varscan2
- GGT1 | c.241C>G p.H81D | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs756699419, COSV50646074; called by muse, mutect2, varscan2
- GRIN2A | c.3373G>T p.E1125* | Nonsense Mutation (SNP) | VAF 34/445 reads (8%) | catalogued as rs1200593226, COSV58026502, COSV58058380; called by muse, mutect2
- HHLA2 | c.839A>G p.N280S | Missense Mutation (SNP) | VAF 24/491 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.058); catalogued as COSV100755256, COSV63320229; called by muse, mutect2
- HTR1B | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64052017; called by muse, mutect2, varscan2
- ITGA8 | c.965G>T p.G322V | Missense Mutation (SNP) | VAF 53/338 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65224832; called by muse, mutect2, varscan2
- LMAN1L | c.1162G>A p.G388R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as rs1054146436, COSV100547571, COSV59000970; called by muse, mutect2, varscan2
- LRGUK | c.2249C>T p.P750L | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs544247071, COSV53638744; called by muse, mutect2
- MTMR4 | c.2394G>T p.M798I | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV60204369; called by muse, mutect2, varscan2
- MTTP | c.1943T>C p.L648P | Missense Mutation (SNP) | VAF 88/256 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV55510365; called by muse, mutect2, varscan2
- OR1M1 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 39/249 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs144608760; called by muse, mutect2, varscan2
- OR51B5 | c.409A>T p.T137S | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56177473; called by muse, mutect2, varscan2
- PCDHGA11 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV54043945; called by muse, mutect2, varscan2
- PDC | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 46/993 reads (5%) | catalogued as COSV100414891; called by muse, mutect2
- PIK3C2B | c.3179A>G p.N1060S | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1173631763, COSV65814551; called by muse, mutect2, varscan2
- PPP1R10 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV64740609; called by muse, mutect2
- RCBTB2 | c.1118-1G>A p.X373_splice | Splice Site (SNP) | VAF 9/88 reads (10%) | catalogued as COSV60652112; called by muse, mutect2
- RYR1 | c.8580dup p.D2861Rfs*3 | Frame Shift Ins (INS) | VAF 4/46 reads (9%) | catalogued as rs757481998; called by pindel, varscan2
- SCRN1 | c.22T>C p.Y8H | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.492); catalogued as COSV54134613; called by muse, mutect2, varscan2
- SCTR | c.891C>G p.I297M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1177119970, COSV50032830; called by muse, mutect2
- SEC61A1 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 28/117 reads (24%) | catalogued as COSV54579274; called by muse, mutect2, varscan2
- SNAP91 | c.2510G>C p.G837A | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV52135819, COSV99535106; called by muse, mutect2
- SPO11 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as rs141106732; called by muse, mutect2, varscan2
- STAG3 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs149765159; called by muse, mutect2, varscan2
- TRPM2 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs150593294, COSV55965307; called by muse, mutect2
- UHRF1BP1L | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 60/291 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs766723484, COSV54437555; called by muse, mutect2, varscan2
- DMBT1 | c.7173_7175del p.S2393del (on ENST00000338354 / NM_001377530.1; = p.S1636del on NM_004406.3) | In Frame Del (DEL) | VAF 33/190 reads (17%) | called by mutect2, pindel, varscan2
- KDM7A | c.2525del p.S842Ifs*23 | Frame Shift Del (DEL) | VAF 37/141 reads (26%) | called by mutect2, pindel, varscan2
- AGRN | c.342C>T p.I114= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV65072646; called by muse, mutect2, varscan2
- COG5 | c.684C>T p.V228= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs773862978, COSV51765835; called by muse, mutect2, varscan2
- DLL4 | c.789C>A p.T263= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV51073712; called by muse, mutect2, varscan2
- DNAH7 | c.10335A>T p.L3445= | Silent (SNP) | VAF 106/486 reads (22%) | catalogued as COSV56789261; called by muse, mutect2, varscan2
- LCA5L | c.1527C>A p.G509= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV55747554; called by muse, mutect2, varscan2
- MAN2A2 | c.774C>G p.S258= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV64640111; called by muse, varscan2
- TACR3 | c.255C>T p.I85= | Silent (SNP) | VAF 32/339 reads (9%) | catalogued as COSV59203863; called by muse, mutect2
- TAFA4 | c.222C>G p.V74= | Silent (SNP) | VAF 12/254 reads (5%) | catalogued as COSV55146850; called by muse, mutect2
- TULP3 | c.1176G>A p.Q392= | Silent (SNP) | VAF 6/107 reads (6%) | catalogued as COSV68118847; called by muse, mutect2
- WDSUB1 | c.60C>T p.F20= | Silent (SNP) | VAF 12/258 reads (5%) | catalogued as COSV63067291; called by muse, mutect2
- WWC1 | c.1686C>T p.L562= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV54653807; called by muse, mutect2, varscan2
